Somatic mutation profile of tumor specimen TARGET-30-PATILE-01A (aliquot TARGET-30-PATILE-01A-01D) from TARGET case TARGET-30-PATILE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Spinal meninges; Age at diagnosis: 2.3 years (824 days).
Specimen TARGET-30-PATILE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cbac65d-0d01-4116-8fca-bcf56ead2641.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATILE-10A (Blood Derived Normal), aliquot TARGET-30-PATILE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68da2863-d613-47fb-9703-414107aebd50

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCR2 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs75236779, COSV52748528; called by muse, mutect2, varscan2
- FOXD4L3 | c.1065C>A p.C355* | Nonsense Mutation (SNP) | VAF 46/229 reads (20%) | catalogued as COSV61551370; called by muse, mutect2, varscan2
- GPRIN2 | c.724_725insTGGAGGTGG p.R242delinsMEVG | In Frame Ins (INS) | VAF 4/37 reads (11%) | catalogued as COSV65400221; called by mutect2*, pindel
- HIF1A | c.2135C>A p.A712D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV60189079; called by muse, mutect2, varscan2
- USP49 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51896676; called by muse, mutect2, varscan2
- ITGB6 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GPD1L | c.648C>T p.C216= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs145648143; called by mutect2, varscan2
